Surgical pathology report (de-identified scan), TCGA case TCGA-36-1575, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site BC Cancer Agency, specimen TCGA-36-1575-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Consultation Report

TCGA-36-1575

Case Number:

Collect Date:

Receive Date:

Date Reported:

Patient's Name:

MRN:

PHN:

DOB/Gender:

Ordering Physician:

Final Diagnosis:

1. Omentectomy showing:

- a. scattered adhesions with an adherent tubal fimbria
- b. no tumour identified

2. Left salpingo-oophorectomy showing high grade papillary serous cystadenocarcinoma of the ovary, 17 cm size:

- a. tumour is confined to the ovary, with no surface capsular tumour growth present
- b. no angiolymphatic invasion
- c. tubo-ovarian adhesions

3. Hysterectomy with right salpingo-oophorectomy showing:

- a. grade 1 endometrioid adenocarcinoma of the uterine corpus
- b. inner half myometrial invasion
- c. background of cystic endometrial atrophy
- d. no angiolymphatic invasion
- e. multiple uterine leiomyomata (at least 10)
- f. benign cervix with multiple Nabothian cysts
- g. unremarkable cul de sac
- h. scattered uterine adhesions
- i. single metastatic nodule of serous tumour in the right ovary, 0.3 cm size, confined to the ovary, close to, but not at, the capsular surface
- j. focal ovarian adhesions
- k. unremarkable right fallopian tube

Final Diagnosis Comment:

The accompanying peritoneal washings are negative for tumour.

Clinical History as Provided by Submitting Physician:

Pelvic mass

A. Left ovary

B. Uterus, tube + right ovary

C. Omentum

Specimens Received:

A: left ovary

B: uterus, tube + right ovary

C: omentum

[page 2 of 2]
Gross Description:

Specimen is received in three containers each labelled with the patient's name.

Container "A" is labelled "omentum" and consists of an apron of greater omentum measuring 30 x 11 x 1.1 cm. Grossly, the specimen consists of unremarkable yellowish fat. Representative sections are submitted in cassettes "A1"- "A10".

Container "B" is labelled "left ovary plus fallopian tube" and consists of cystic ovary measuring 17 x 12 x 8.5 cm, with total weight 1291 grams. The attached fallopian tube is 5.5 cm in length, and 0.5 cm in diameter. The fimbriated end is adherent to the ovary. The external surface of the ovary is tan-white with adhesions; grossly no tumor is present on the external surface.

Sections show a multilocular ovary with one main locule 15 cm in greatest dimension, and several smaller locules varying from a few millimeters to 3.5 cm in diameter. The inner surface of the larger locule varies from smooth to finely papillary to roughened with necrotic loosely adherent membranous material and focal hemorrhage. The cyst wall is mostly 0.2-0.3 cm thick. A 7 cm area is more solid, homogenous, and tan-white, with focal papillary structures.

Representative sections are submitted as follows:

"B1"- "B5" -solid area

"B6"- "B8" -representative section of the cyst wall

"B9"- "B10" -fallopian tube

Container "C" is labelled "uterus, tubes and right ovary" and consists of uterus with right adnexa, the total weight 130 grams. The external surface is tan-white, glistening, with three exophytic nodules bulging from the serosal surface measuring up to 4.5 cm in greatest dimension. The uterus measures 7.5 cm from superior to inferior, 5.5 cm side by side, 9 cm from anterior to posterior. The cervix measures 1.5 cm x 1 cm. The mucosa is tan-white and unremarkable. The endocervical canal is mostly unremarkable with a few cysts with cloudy mucinous content. The thickness of the endometrium is 0.3-0.4 cm. It is uneven, and partially cystic and polypoid. The anterior and posterior myometrium are distorted by well-circumscribed nodules. One on the anterior surface is a fibroid-like nodule measuring 2.2 cm in greatest dimension. On the posterior surface, a similar nodule is 4 cm in greatest dimension. An additional 6 smaller intramural fibroid-like nodules are present. The thickness of myometrium is otherwise 1.3 cm. The right fallopian tube measures 7 cm in length, and up to 0.5 cm in diameter. The right ovary measures 4 cm x 0.9 x 0.6 cm. These structures are grossly unremarkable.

Representative sections are submitted as follows:

"C1"- "C2" -cervix

"C3" -isthmus

"C4" -cul-de-sac

"C5"- "C10" -representative section of the myometrium

"C11" -right fallopian tube

"C12" -right ovary

Additional sections of the endometrium are submitted as "C13"- "C15".

Source: NCI Genomic Data Commons file 48b0b9ff-f6e1-4698-981d-1279cf5e1cff (TCGA-36-1575.44CF8EEE-71B1-4499-815A-7D1C3092DBE3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).